CTSP case CTSP-AD1R — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/19ec7505-20c7-4ba2-bf08-4a8875cb2639

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Dead; Days to death: 1,645 days (4.5 years); Year of death: 2014; Cause of death: Cancer Related.

Diagnoses (1)
1. Intravascular large B-cell lymphoma: ICD-O-3 morphology code: 9712/3; Age at diagnosis: 66.2 years (24,180 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Days to last follow up: 1,645 days (4.5 years); Best overall response: Complete Response; Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): High-Intermediate Risk.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 47 kg; Height: 152 cm; BMI: 20.3.

Biospecimens (1 sample)
- Sample DLBCL11316-sample: Sample type: Tumor; Tissue type: Tumor.
